FM case AD15989 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms.
https://portal.gdc.cancer.gov/cases/bb9daec3-4808-4fd9-980b-306359001f69

Female, 56.5 years: Myoepithelial carcinoma (ICD-O-3 8982/3); specimen biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Tumor.
